Somatic mutation profile of tumor specimen 0DCER5 from CCDI case PBBMEH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.2 years (4,442 days).
Specimen 0DCER5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8733ae5-471f-40a1-b9e9-9d5da7da5925.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCEQX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0eceedb-f44d-4992-b7c1-112e22011469

The open-access MAF lists 18 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Intron 2, 3'UTR 1, 3'Flank 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP4 | c.2909G>A p.R970H | Missense Mutation (SNP) | VAF 64/1244 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755378449; called by muse, mutect2
- GPR62 | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 18/387 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1479464743; called by muse, mutect2
- MYO10 | c.3161C>G p.A1054G | Missense Mutation (SNP) | VAF 458/1157 reads (40%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV57022286; called by muse, mutect2, varscan2
- AMER1 | c.2089G>C p.D697H | Missense Mutation (SNP) | VAF 462/500 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, varscan2
- MALSU1 | c.20del p.V7Gfs*8 | Frame Shift Del (DEL) | VAF 72/374 reads (19%) | called by mutect2, varscan2
- OR10S1 | c.911T>C p.L304S | Missense Mutation (SNP) | VAF 233/788 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- PLAT | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 302/703 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 53/1115 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- GLI2 | c.4611C>T p.P1537= (on ENST00000361492 / NM_001374353.1; = p.P1554= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 735/1623 reads (45%) | catalogued as rs1461836513; called by muse, mutect2, varscan2
- MYO5B | c.2941C>T p.L981= | Silent (SNP) | VAF 365/1068 reads (34%) | catalogued as COSV53213420; called by muse, mutect2, varscan2
- NUP205 | c.2467C>T p.L823= | Silent (SNP) | VAF 324/787 reads (41%) | called by muse, mutect2, varscan2
- OMA1 | c.825A>G p.K275= | Silent (SNP) | VAF 256/827 reads (31%) | called by mutect2, varscan2
- SLC43A1 | c.1197C>T p.D399= | Silent (SNP) | VAF 360/843 reads (43%) | catalogued as rs766364249; called by muse, mutect2, varscan2
- DDX60 | c.4270-45T>A | Intron (SNP) | VAF 13/196 reads (7%) | called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- NRCAM | c.-58T>G | 5'UTR (SNP) | VAF 15/429 reads (3%) | called by muse, mutect2
- OR6Y1 | chr1:158547111 A>G | 3'Flank (SNP) | VAF 193/447 reads (43%) | called by muse, mutect2, varscan2
- TNFRSF4 | c.*62C>T | 3'UTR (SNP) | VAF 100/217 reads (46%) | catalogued as rs899367341; called by muse, mutect2, varscan2
